Gene-level copy-number profile of tumor specimen ALCH-B1VJ-TTP1-A from ALCHEMIST case ALCH-B1VJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 78.8 years (28,764 days).
Specimen ALCH-B1VJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b7e1cc36-78ec-4774-a756-ae2dc53759d8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1VJ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/24a3d3f9-090b-4063-baf6-6f397783cff4

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 709; copy number 1: 35,123; copy number 2: 18,446; copy number 3: 4,106; copy number 4: 484; copy number 5: 2; copy number 6: 1; copy number 7: 1; copy number 8: 26.

Homozygous deletions (total copy number 0; autosomes only): 166 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:129,591,349–129,591,635, 1 gene (within-gene range 0–1): RN7SL752P.
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr4:151,027,090–151,027,617, 1 gene: AK4P6.
- chr5:22,139,247–22,152,356, 2 genes (within-gene range 0–1): AC139497.1, PMCHL1.
- chr5:71,074,225–71,093,193, 1 gene: OCLNP1.
- chr5:112,161,485–112,257,309, 4 genes (within-gene range 0–1): SNORA13, AC010261.1, AC010261.2, AC104126.1.
- chr6:29,887,294–29,929,232, 7 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K.
- chr7:151,048,292–151,076,526, 4 genes (within-gene range 0–2): ASIC3, CDK5, SLC4A2, AC010973.3.
- chr9:93,121,496–93,148,556, 2 genes: NINJ1, AL390760.1.
- chr9:124,514,938–124,516,056, 1 gene: AL354979.1.
- chr10:87,341,685–87,357,882, 1 gene (within-gene range 0–2): LINC00863.
- chr10:87,376,896–87,378,481, 1 gene: NPAP1P3.
- chr12:31,363,481–31,369,301, 2 genes: LINC02387, U6.
- chr12:123,250,112–123,272,334, 2 genes (within-gene range 0–1): CDK2AP1, AC068768.1.
- chr14:106,257,762–106,324,760, 14 genes (within-gene range 0–1): IGHV3-22, IGHVII-22-1, IGHVIII-22-2, IGHV3-23, IGHV1-24, HOMER2P2, LINC00226, IGHV3-25, IGHVIII-25-1, IGHV2-26, IGHVIII-26-1, IGHVII-26-2, IGHV7-27, IGHV4-28.
- chr14:106,335,082–106,335,613, 1 gene (within-gene range 0–1): IGHV3-30.
- chr14:106,349,283–106,349,792, 1 gene (within-gene range 0–1): IGHV4-31.
- chr14:106,359,793–106,360,324, 1 gene (within-gene range 0–1): IGHV3-33.
- chr15:25,193,321–25,225,284, 18 genes (within-gene range 0–1): SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:43,593,054–43,604,901, 1 gene (within-gene range 0–1): CKMT1B.
- chr15:43,602,543–43,602,648, 1 gene (within-gene range 0–1): RNU6-554P.
- chr15:43,637,632–43,643,023, 2 genes (within-gene range 0–1): RNU6-610P, AC011330.2.
- chr15:85,750,336–85,794,925, 5 genes: AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1.
- chr16:8,848,105–8,870,032, 4 genes (within-gene range 0–1): AC022167.2, CARHSP1, AC022167.1, AC022167.4.
- chr16:89,268,104–89,273,044, 1 gene (within-gene range 0–2): AC137932.3.
- chr18:32,075,885–32,131,561, 4 genes (within-gene range 0–2): AC011825.1, AC011825.4, RNF138, AC011825.2.
- chr18:32,176,050–32,220,404, 3 genes (within-gene range 0–2): RNA5SP453, MEP1B, CLUHP6.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–1): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr19:5,823,802–5,828,324, 1 gene: NRTN.
- chr19:28,949,437–29,015,160, 4 genes (within-gene range 0–1): AC011524.1, AC011524.2, RNA5SP470, LINC01532.
- chr20:3,786,772–3,876,123, 5 genes: CDC25B, LINC01730, AL109804.1, AP5S1, MAVS.
- chr20:8,019,180–8,043,512, 1 gene (within-gene range 0–1): AL021396.1.
- chr20:21,499,261–21,514,064, 4 genes: AL133325.3, GSTM3P1, NKX2-2, NKX2-2-AS1.
- chr20:25,284,915–25,285,588, 1 gene (within-gene range 0–1): AL121772.3.
- chr20:31,637,912–31,645,006, 1 gene: COX4I2.
- chr21:7,744,962–9,368,775, 44 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12.
- chr21:10,397,644–10,516,431, 2 genes (within-gene range 0–1): AF254983.2, BAGE2.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 4,620 genes in 49 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–153,616,986, 427 genes, copy number 3–7 (broad region; genes not listed).
- chr1:153,717,303–163,923,873, 431 genes, copy number 3–4 (broad region; genes not listed).
- chr1:221,508,559–248,937,043, 637 genes, copy number 3 (broad region; genes not listed).
- chr2:38,132,637–38,286,410, 6 genes, copy number 4: AC009229.2, RNU6-951P, AC009229.3, AC009229.1, RPL7P12, GAPDHP25.
- chr2:79,185,231–80,648,861, 3 genes, copy number 3 (within-gene range 2–3): CTNNA2, AC011754.2, CTNNA2-AS1.
- chr2:79,636,862–85,460,252, 67 genes, copy number 3 (broad region; genes not listed).
- chr2:85,602,856–96,023,380, 266 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr2:96,145,602–99,322,741, 88 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr3:173,396,284–174,378,005, 6 genes, copy number 3: NLGN1, AC092967.1, NLGN1-AS1, RN7SKP234, ANAPC15P2, AC069218.1.
- chr4:49,096–2,069,089, 75 genes, copy number 3 (broad region; genes not listed).
- chr4:3,576,869–7,112,399, 74 genes, copy number 3 (broad region; genes not listed).
- chr4:91,603,275–91,904,335, 3 genes, copy number 3: AC110774.1, KRT19P6, AC093810.1.
- chr4:114,598,770–117,691,188, 30 genes, copy number 3–4: UGT8, MIR577, CIR1P2, RN7SL808P, NDST4, MRPS33P3, RPF2P2, PGAM4P2, KRT18P21, AC027613.1, EIF3KP3, TTC39CP1, MTRNR2L13, MIR1973, TRMT112P1, CUL4AP1, AC106892.1, ACTN4P1, AC093765.3, AC093765.2, RNU6-119P, AC093765.1, TRAM1L1, AC107399.1, LINC02262, LINC02263, LINC01378, RPSAP35, NT5C3AP1, AC092661.1.
- chr4:119,135,832–119,395,335, 8 genes, copy number 3: MYOZ2, AC092656.1, USP53, C4orf3, FABP2, KLHL2P1, RNU4-33P, AC110373.1.
- chr4:119,409,333–119,552,025, 3 genes, copy number 3 (within-gene range 1–3): AC093752.3, RNU6-1217P, AC093752.1.
- chr4:119,494,397–119,964,293, 6 genes, copy number 3: PDE5A, AC080089.1, LINC01365, AC097173.1, LINC02502, Y_RNA.
- chr5:58,198–667,168, 25 genes, copy number 3 (within-gene range 2–3): AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72.
- chr5:795,606–2,262,023, 47 genes, copy number 3: ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2, Y_RNA, AC092266.1.
- chr5:13,553,654–14,532,128, 6 genes, copy number 3 (within-gene range 1–3): NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1.
- chr5:180,967,189–181,006,727, 4 genes, copy number 4: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr7:37,032–5,425,414, 110 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr7:5,526,409–6,608,726, 35 genes, copy number 3: ACTB, AC006483.2, AC006483.1, FSCN1, RNF216, RNF216-IT1, MIR6874, ZNF815P, RN7SL556P, OCM, CCZ1, RSPH10B, PMS2, Y_RNA, AIMP2, SNORA80D, EIF2AK1, ANKRD61, RN7SL851P, RNU6-218P, AC004895.1, USP42, CYTH3, Y_RNA, FAM220A, AC009412.1, RPSAP73, RAC1, DAGLB, KDELR2, AC072052.1, GRID2IP, ZDHHC4, AC079742.1, C7orf26.
- chr7:6,663,974–45,768,985, 646 genes, copy number 3 (broad region; genes not listed).
- chr7:45,888,360–57,837,046, 224 genes, copy number 3–8 (broad region; genes not listed).
- chr7:99,616,946–99,820,086, 9 genes, copy number 3: ZSCAN25, AC005020.1, CYP3A5, CYP3A7-CYP3A51P, CYP3A51P, CYP3A7, CYP3A4, AC069294.1, CYP3A137P.
- chr10:14,061–5,842,132, 101 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr10:6,271,169–13,668,445, 109 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr10:57,955,295–58,869,528, 13 genes, copy number 3: AC006484.1, MRPS35P3, AC026884.1, IPMK, TPT1P10, CISD1, AC016396.1, AC016396.2, UBE2D1, TFAM, BICC1, FAM133CP, RN7SKP196.
- chr11:68,460,731–68,616,711, 3 genes, copy number 3: PPP6R3, NDUFA3P2, AP003096.1.
- chr11:128,965,060–129,279,324, 4 genes, copy number 3: ARHGAP32, RNU6-876P, Y_RNA, RNU6-874P.
- chr14:105,093,609–105,100,131, 2 genes, copy number 5: LINC02298, AL512356.4.
- chr15:34,489,002–34,521,791, 3 genes, copy number 3: HNRNPLP2, FSCN1P1, DNM1P5.
- chr15:101,875,964–101,979,093, 12 genes, copy number 3–6: OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.
- chr17:58,755,854–83,240,804, 796 genes, copy number 3 (broad region; genes not listed).
- chr19:1,228,287–1,239,522, 2 genes, copy number 3–4 (within-gene range 1–4): CBARP, AC004221.1.
- chr20:26,008,791–26,020,684, 3 genes, copy number 3: AL078587.1, AL078587.2, AL450124.1.
- chr20:49,293,394–49,484,297, 2 genes, copy number 3 (within-gene range 2–3): KCNB1, AL035685.1.
- chr21:35,472,095–35,887,807, 6 genes, copy number 3: RPL34P3, EZH2P1, AF015720.1, MIR802, RPS20P1, PPP1R2P2.
- chr21:36,943,267–45,264,548, 235 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr22:31,051,630–33,145,861, 81 genes, copy number 3 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 32,810. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
